Somatic mutation profile of tumor specimen 0DPSNO from CCDI case PBCDID, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Maxillary sinus; Age at diagnosis: 14.4 years (5,273 days).
Specimen 0DPSNO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c04abee5-f48c-4664-9d0a-aea5e2f631af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPSN1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31975429-5ec5-42d1-9919-56d7058931b0

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYLC2 | c.622G>A p.G208S | Missense Mutation (SNP) | VAF 326/1613 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs1394472891; called by muse, mutect2, varscan2
- EHMT1 | c.1877A>G p.Y626C | Missense Mutation (SNP) | VAF 79/437 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs762449462; called by muse, mutect2, varscan2
- PIWIL3 | c.1399G>A p.V467I | Missense Mutation (SNP) | VAF 119/680 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.029); catalogued as rs757983793, COSV59993796; called by muse, mutect2, varscan2
- ARHGEF12 | c.299A>G p.D100G | Missense Mutation (SNP) | VAF 110/560 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ATP2B3 | c.686G>T p.G229V | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HGS | c.1435G>A p.D479N | Missense Mutation (SNP) | VAF 73/419 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IQGAP3 | c.2915A>T p.K972M | Missense Mutation (SNP) | VAF 104/513 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- SFMBT2 | c.2159A>C p.E720A | Missense Mutation (SNP) | VAF 55/262 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- TREML2 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 141/615 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- USP17L1 | c.665A>G p.D222G | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDC42BPG | c.3522C>T p.P1174= | Silent (SNP) | VAF 27/163 reads (17%) | catalogued as rs747504139; called by muse, mutect2, varscan2
- DIP2A | c.141A>G p.A47= | Silent (SNP) | VAF 133/668 reads (20%) | called by muse, mutect2, varscan2
- PTPRK | c.1485A>G p.V495= | Silent (SNP) | VAF 152/775 reads (20%) | catalogued as rs761118126; called by muse, mutect2, varscan2
- ZFP42 | c.660G>A p.A220= | Silent (SNP) | VAF 98/531 reads (18%) | catalogued as rs766468992, COSV58818972; called by muse, mutect2, varscan2
